Somatic mutation profile of tumor specimen TCGA-2G-AALZ-01A (aliquot TCGA-2G-AALZ-01A-11D-A42Y-10) from TCGA case TCGA-2G-AALZ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dab08d3e-2de0-4653-beaa-3880bce57f5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALZ-10A (Blood Derived Normal), aliquot TCGA-2G-AALZ-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1e51ee5-debf-41d1-b9aa-ab1d7952aa64

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ECPAS | c.4637C>T p.A1546V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs1332017850; called by muse, mutect2
- FAM149A | c.1745G>A p.G582D (on ENST00000356371 / NM_001367768.2; = p.G291D on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as rs1188668729; called by muse, mutect2, varscan2
- NPLOC4 | c.153C>G p.N51K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.801); called by muse, mutect2
- KMT2D | c.15474G>A p.E5158= | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- SHKBP1 | c.1371T>C p.S457= | Silent (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- COG3 | c.-2C>T | 5'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
